Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8331, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8331-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

female with right renal mass. For right radical nephrectomy.

Specimens Submitted:

1: SP: Right kidney

2: SP: Paracaval lymph node

3: SP: Right adrenal

DIAGNOSIS:

- 1) KIDNEY, RIGHT; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CHROMOPHOBE TYPE.
- THE PATTERN OF GROWTH IS ACINAR AND SOLID.
- THE TUMOR GREATEST DIAMETER IS 10.0 CM.
- THE TUMOR EXTENDS INTO THE RENAL PELVIS.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS FOCAL GLOMERULOSCLEROSIS.
- 2) LYMPH NODE, PARACAVAL; BIOPSY:
- FIFTEEN BENIGN LYMPH NODES (0/15).
- 3) ADRENAL GLAND, RIGHT; RESECTION:
- ADRENOCORTICAL ADENOMA, MEASURING 0.9 X 0.8 X 0.7 CM.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	A103	
	INH	
	CD10	
	RCC	
	NEG CONT	
	IMM RECUT	

[page 2 of 3]
1) The specimen is received fresh, labeled "Right Kidney". It consists of a kidney with attached perinephric fat, weighing 510 grams and measuring 13 x 10 x 7.5 cm. A portion of ureter is identified measuring 6 cm in length x 0.3 cm in diameter. The ureter is serially sectioned revealing a grossly unremarkable cut surface. Vessels are identified on the hilum, ranging in size from 0.5 to 0.7 cm in length with a diameter measuring 0.2 cm. The kidney is partially covered by a thick portion of perinephric fat which measures 15 x 6 x 0.7 cm. The kidney is bisected revealing a large, yellow-tan, focally hemorrhagic, partially necrotic, variegated tumor mass located predominantly on the upper two-thirds of the kidney, involving the renal cortex, medulla and pelvis, entirely measuring 10 x 9.5 x 9 cm. The tumor appears grossly to be confined within the renal capsule. The tumor is serially sectioned, revealing a yellow-tan to red-gray, hemorrhagic and friable cut surface. On the center of the tumor is a more well-circumscribed, markedly hemorrhagic area measuring 4 x 4 x 2 cm. A small portion of residual normal renal parenchyma is identified. Photographs are taken. Representative sections are submitted. A section from the tumor is submitted for TPS and EM.

Summary of Sections:

UM – ureter margin

RV – renal vessel

PF – perinephric fat

NK – normal kidney

PEL – pelvis

T – tumor

AG – additional perinephric fat

HAT - hemorrhagic area of the tumor

2) The specimen is received in formalin, labeled "Paracaval Lymph Node". It consists of multiple irregular fragments of yellow-tan, lobulated adipose tissue measuring in aggregate 5.5 x 3 x 2 cm. Twelve lymph nodes are identified, ranging in size from 0.3 to 1.7 cm. The entire lymph nodes are submitted. The two largest lymph nodes are bisected and placed in the first two cassettes.

Summary of Sections:

PCN – paracaval lymph nodes (2pcn2-bisected large lymph node and one smaller lymph node)

3) The specimen is received in formalin, labeled "Right Adrenal". It consists of an adrenal gland with one edge closed by multiple staples, entirely measuring 5.5 x 2.5 x 1.8 cm. The resection margin is inked black. The specimen is serially sectioned revealing a well-circumscribed, tan-yellow, soft nodule measuring 0.9 x 0.8 x 0.7 cm. The rest of the adrenal gland appears grossly unremarkable. The specimen is entirely submitted.

Summary of Sections:

ADG – adrenal gland

SM – stapled margin

Summary of Sections:

Part 1: SP: Right kidney (am)

Block	Sect. Site	PCs
2	AG	3
3	HAT	4
2	NK	4
2	PEL	4
2	PF	3
1	RV	4
6	T	7
1	UM	1

Part 2: SP: Paracaval lymph node (pjm)

Block	Sect. Site	PCs
-------	------------	-----

Source: NCI Genomic Data Commons file 33c5fed2-1295-4dc6-86f9-8da96c4721e2 (TCGA-KL-8331.13B03F3F-1CA6-49C2-B6A6-D935E98446BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).